Somatic mutation profile of tumor specimen MP2PRT-PAVKWM-TMP1-A (aliquot MP2PRT-PAVKWM-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVKWM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,135 days).
Specimen MP2PRT-PAVKWM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb24d9f1-8422-4b79-ac61-ac3f6b2e8711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKWM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKWM-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6228cdf4-c28d-4705-98a5-d05f0b1889e6

The open-access MAF lists 110 somatic variants for this specimen: 73 protein-altering or splice-affecting, 29 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 29, Nonsense Mutation 5, Intron 5, 3'UTR 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP35 | c.1790G>T p.R597I | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101351687, COSV68329418; called by muse, mutect2, varscan2
- ARHGAP6 | c.2449C>T p.R817C (on ENST00000337414 / NM_013427.3; = p.R614C on NM_013423.3) | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as rs750326704; called by muse, mutect2
- DNAH1 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 28/286 reads (10%) | catalogued as COSV101327197; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2310G>C p.E770D | Missense Mutation (SNP) | VAF 55/466 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV62566775; called by muse, mutect2, varscan2
- EPHA2 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs1295018439; called by muse, mutect2, varscan2
- ERICH3 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100445475; called by muse, mutect2
- FAT4 | c.4412T>C p.I1471T | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV67900110; called by muse, mutect2, varscan2
- GABRA5 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 15/439 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171210102, COSV59477866; called by muse, mutect2
- GABRG2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 12/236 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV62722295; called by muse, mutect2
- HIP1 | c.2864C>G p.S955C | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs966145586; called by muse, mutect2
- HSPA6 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs760084677, COSV59060796; called by muse, mutect2
- KDM2A | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 72/562 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs760984462, COSV58191819; called by muse, varscan2
- KLHL21 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 44/844 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV99071371; called by muse, mutect2
- LLGL2 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 97/734 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs915309363; called by muse, mutect2, varscan2
- MAD2L1 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV56636702; called by muse, mutect2
- MATN3 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 205/425 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778152107; called by muse, mutect2, varscan2
- MLNR | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 87/608 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as COSV54531774; called by muse, mutect2, varscan2
- MPP6 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV56037146; called by muse, mutect2
- MYOZ1 | c.317C>G p.S106* | Nonsense Mutation (SNP) | VAF 29/475 reads (6%) | catalogued as COSV63772445; called by muse, mutect2
- NCOR1 | c.4181C>G p.S1394* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV51962844; called by muse, mutect2
- NCOR1 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs1398361404; called by muse, mutect2, varscan2
- NDNF | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.954); catalogued as COSV65634415; called by muse, mutect2
- NDUFA11 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 190/428 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53135684; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 146/346 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAAF1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 20/413 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV60155572; called by muse, mutect2
- PAPPA | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs764118858, COSV104407458; called by muse, mutect2, varscan2
- PGRMC1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 61/387 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV54291964; called by muse, mutect2, varscan2
- PSG4 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54935829; called by mutect2, varscan2
- RBM28 | c.1937C>T p.S646L | Missense Mutation (SNP) | VAF 68/515 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.261); catalogued as rs1400386065; called by muse, mutect2, varscan2
- RESF1 | c.2543C>T p.S848L | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1354994077; called by muse, mutect2, varscan2
- SLC25A3 | c.648C>G p.F216L (on ENST00000228318 / NM_005888.3; = p.F215L on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.197); catalogued as rs1451893475; called by muse, mutect2, varscan2
- SMARCAD1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV62773764; called by muse, mutect2
- STON1-GTF2A1L | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1269953741; called by muse, mutect2
- VPS37D | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1208391577; called by muse, mutect2
- ABL2 | c.964G>A p.D322N (on ENST00000502732 / NM_007314.4; = p.D307N on NM_005158.5) | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ACSL6 | c.1548C>G p.F516L (on ENST00000379240; = p.F541L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- AGK | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- ARHGAP35 | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ATOH8 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 26/746 reads (3%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- ATP13A4 | c.2686G>T p.A896S | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CELSR1 | c.8219G>A p.C2740Y | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- CLCN1 | c.1351C>G p.H451D | Missense Mutation (SNP) | VAF 27/511 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- CLCN6 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, mutect2
- CLEC16A | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- COL6A5 | c.3253G>C p.D1085H | Missense Mutation (SNP) | VAF 94/268 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CRY2 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 24/405 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CSMD3 | c.2260G>A p.D754N (on ENST00000297405 / NM_001363185.1; = p.D650N on NM_052900.3) | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DNAH1 | c.1728G>C p.M576I | Missense Mutation (SNP) | VAF 62/444 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH17 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 83/884 reads (9%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- ITGB8 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 103/270 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- KDM6A | c.3080G>C p.R1027T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2
- KRTAP27-1 | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 221/425 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MTHFD1 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH15 | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 36/504 reads (7%) | called by muse, mutect2
- NCOR1 | c.4910C>G p.P1637R | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10G6 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- PKDREJ | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- POGLUT2 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PSG3 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- RHNO1 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2
- RHNO1 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 19/319 reads (6%) | called by muse, mutect2
- SLC24A1 | c.2386G>C p.D796H | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLC44A1 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 187/414 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TCHHL1 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 167/379 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TDRD12 | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TOP3B | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- USH2A | c.14828A>G p.N4943S | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- VCAN | c.6020C>T p.S2007L | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- ZFP14 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2
- ZMYND8 | c.2902G>C p.E968Q (on ENST00000311275 / NM_001363741.2; = p.E942Q on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/345 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF408 | c.1913C>A p.P638H | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- ZSCAN18 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 18/469 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ADAMTSL3 | c.4404C>T p.L1468= | Silent (SNP) | VAF 22/435 reads (5%) | called by muse, mutect2
- ADCY10 | c.2748G>A p.L916= | Silent (SNP) | VAF 15/355 reads (4%) | catalogued as rs1303236688; called by muse, mutect2
- COL25A1 | c.1896G>A p.L632= | Silent (SNP) | VAF 55/554 reads (10%) | catalogued as rs774443798; called by muse, mutect2
- DNAH1 | c.1482G>A p.Q494= | Silent (SNP) | VAF 30/335 reads (9%) | called by muse, mutect2
- DOK6 | c.42G>A p.V14= | Silent (SNP) | VAF 47/552 reads (9%) | called by muse, mutect2
- FBXW2 | c.852C>G p.L284= | Silent (SNP) | VAF 20/320 reads (6%) | catalogued as COSV100535262; called by muse, mutect2
- HMGCS1 | c.312G>A p.V104= | Silent (SNP) | VAF 59/330 reads (18%) | catalogued as COSV57291576; called by muse, mutect2, varscan2
- IGF2BP3 | c.1629C>T p.F543= | Silent (SNP) | VAF 40/328 reads (12%) | called by muse, mutect2, varscan2
- KRT27 | c.771G>A p.L257= | Silent (SNP) | VAF 50/429 reads (12%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.2406C>G p.V802= | Silent (SNP) | VAF 233/487 reads (48%) | called by muse, mutect2, varscan2
- MED26 | c.1470G>A p.L490= | Silent (SNP) | VAF 16/544 reads (3%) | called by muse, mutect2
- MYO1D | c.2721G>C p.L907= | Silent (SNP) | VAF 22/275 reads (8%) | called by muse, mutect2
- NDST4 | c.2356C>T p.L786= | Silent (SNP) | VAF 28/329 reads (9%) | catalogued as rs914359170; called by muse, mutect2
- OR6N1 | c.234C>T p.I78= | Silent (SNP) | VAF 42/313 reads (13%) | catalogued as COSV58650342; called by muse, mutect2, varscan2
- OR6V1 | c.240C>G p.L80= | Silent (SNP) | VAF 81/620 reads (13%) | catalogued as COSV101389556; called by muse, mutect2, varscan2
- PGR | c.591C>T p.L197= | Silent (SNP) | VAF 301/690 reads (44%) | catalogued as rs1278512543, COSV54797781; called by muse, mutect2, varscan2
- PRTN3 | c.444C>T p.H148= | Silent (SNP) | VAF 288/664 reads (43%) | catalogued as rs368260683, COSV99311620; called by muse, mutect2, varscan2
- RIPOR1 | c.861C>T p.V287= (on ENST00000379312 / NM_001193522.2; = p.V283= on NM_024519.4) | Silent (SNP) | VAF 42/490 reads (9%) | called by muse, mutect2
- RTF1 | c.1977C>T p.F659= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- SCN2A | c.3033G>A p.Q1011= | Silent (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1245G>C p.L415= | Silent (SNP) | VAF 13/366 reads (4%) | catalogued as COSV53846499; called by muse, mutect2
- SPTBN1 | c.2730G>A p.Q910= | Silent (SNP) | VAF 53/561 reads (9%) | called by muse, mutect2
- SYTL2 | c.2718C>G p.L906= (on ENST00000528231 / NM_001162951.2; = p.L882= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 133/322 reads (41%) | called by muse, mutect2, varscan2
- TBX2 | c.111C>T p.F37= | Silent (SNP) | VAF 17/511 reads (3%) | called by muse, mutect2
- TMEM140 | c.81G>C p.L27= | Silent (SNP) | VAF 153/371 reads (41%) | called by muse, mutect2, varscan2
- TMEM41A | c.561C>T p.F187= | Silent (SNP) | VAF 130/325 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.68691C>G p.L22897= (on ENST00000591111; = p.L15473= on NM_003319.4) | Silent (SNP) | VAF 16/289 reads (6%) | called by muse, mutect2
- VPS16 | c.1284C>G p.L428= | Silent (SNP) | VAF 55/485 reads (11%) | catalogued as rs759441645; called by muse, mutect2, varscan2
- VWCE | c.576G>A p.Q192= | Silent (SNP) | VAF 20/412 reads (5%) | called by muse, mutect2
- ADARB2 | c.1683-48C>T | Intron (SNP) | VAF 31/784 reads (4%) | called by muse, mutect2
- DNAH10 | c.13307-266G>A | Intron (SNP) | VAF 15/412 reads (4%) | called by muse, mutect2
- FMC1 | chr7:139340419 G>A | 5'Flank (SNP) | VAF 242/568 reads (43%) | called by muse, mutect2, varscan2
- GMEB2 | c.*897G>T | 3'UTR (SNP) | VAF 21/284 reads (7%) | called by muse, mutect2
- LDAH | c.*2006G>C | 3'UTR (SNP) | VAF 6/171 reads (4%) | called by muse, mutect2
- TMEM191C | c.296+73C>T | Intron (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- TRRAP | c.9860-55G>C | Intron (SNP) | VAF 53/455 reads (12%) | called by muse, mutect2, varscan2
- UBE3B | c.630+76C>G | Intron (SNP) | VAF 52/431 reads (12%) | catalogued as rs758080209; called by muse, mutect2, varscan2
